TCGA case TCGA-VS-A9UQ — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Cervix uteri; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2c600a58-98ed-4572-9b6f-edba2719790c

Demographics
Sex at birth: female; Country of residence at enrollment: Brazil; Age at index: 32 years; Vital status: Alive.

Diagnoses (3)
1. Mucinous adenocarcinoma, endocervical type (the primary disease): ICD-O-3 morphology code: 8482/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 32.5 years (11,853 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; FIGO stage: Stage IB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 22.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 154 days; Days to treatment end: 200 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 161 days; Days to treatment end: 184 days; Treatment dose: 2,000 cGy; Treatment outcome: Complete Response; Number of fractions: 4; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2,000 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Chemo concurrent to radiation: No; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Pharmaceutical Therapy, NOS, postoperative.
2. Metastasis of diagnosis 1 (Mucinous adenocarcinoma, endocervical type), site: Ovary. Age at diagnosis: 34.0 years (12,414 days); Days to diagnosis: 561 days (1.5 years); Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Mucinous adenocarcinoma, endocervical type), site: Intra-abdominal lymph nodes. Age at diagnosis: 35.2 years (12,841 days); Days to diagnosis: 988 days (2.7 years); Prior treatment: Yes.

Follow-up (8 entries)
- Day 561 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Ovary; Days to progression: 561 days (1.5 years).
- Days to follow up: 920 days (2.5 years); Disease response: Tumor Free.
- Day 988 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to progression: 988 days (2.7 years).
- Days to follow up: 1,071 days (2.9 years); ECOG performance status: 1.
- Days to follow up: 1,094 days (3.0 years); Disease response: With Tumor.
- Days to follow up: 1,204 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 1,263 days (3.5 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,148.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Current User; Hysterectomy type: Hysterectomy, NOS.
- Timepoint category: Initial Diagnosis; Menopause status: Perimenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Miscarriage.
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 160 cm; BMI: 28.1.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VS-A9UQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 130 mg.
  Slide TCGA-VS-A9UQ-01A-02-TSB: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-VS-A9UQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VS-A9UQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Peri (6-12 months since last menstrual period); History neoadjuvant treatment: No; Tumor status: Tumor free; Pregnancies count miscarriage: 4; Total pregnancy count: 4; Tobacco smoking history indicator: 1; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Mucinous Adenocarcinoma of Endocervical Type; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy type: Wertheim Meiggs; Lymph nodes examined: Yes.
- Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: 3D conformal.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Performance status other timing: Follow up; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form 3: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,263 days; disease-specific survival: no event (censored), 1,263 days; disease-free interval: event (new tumor event after initially disease-free), 561 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 561 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VS-A9UQ-01A-21D-A42N-01): tumor purity 0.58, ploidy 2.04, whole-genome doublings 0.
